Somatic mutation profile of tumor specimen TCGA-GS-A9TU-01A (aliquot TCGA-GS-A9TU-01A-11D-A382-10) from TCGA case TCGA-GS-A9TU, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Diffuse large B-cell lymphoma, NOS; Tissue or organ of origin: Lymph nodes of inguinal region or leg; Age at diagnosis: 45.8 years (16,720 days).
Specimen TCGA-GS-A9TU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c04b122-dc0e-4760-9cf8-29abd404f351.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GS-A9TU-10A (Blood Derived Normal), aliquot TCGA-GS-A9TU-10A-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f5c022b-9bd6-4e09-9052-cdb6cc6fdde2

The open-access MAF lists 70 somatic variants for this specimen: 50 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Frame Shift Ins 3, Nonsense Mutation 3, Splice Region 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DYSF | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs377735262, CM053205; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SRCAP | c.6985C>T p.R2329* | Nonsense Mutation (SNP) | VAF 35/101 reads (35%) | catalogued as rs1555465891, CM1411785, COSV52682925; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AGBL1 | c.3023A>C p.K1008T | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.083); catalogued as COSV101224427; called by muse, mutect2, varscan2
- AGTR1 | c.745T>G p.F249V | Missense Mutation (SNP) | VAF 27/127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100837125, COSV100837232; called by muse, mutect2, varscan2
- ALDH5A1 | c.1034A>C p.Q345P | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV100708953; called by muse, mutect2, varscan2
- APBB1 | c.853C>T p.R285W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.793); catalogued as rs367894248; called by mutect2, varscan2
- ATP10B | c.1880A>C p.K627T | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.171); catalogued as COSV100515986; called by muse, mutect2, varscan2
- CARD11 | c.1191A>C p.L397F | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101211096; called by muse, mutect2, varscan2
- CCDC158 | c.1826T>G p.L609R | Missense Mutation (SNP) | VAF 24/125 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV101187289; called by muse, mutect2, varscan2
- CCDC33 | c.1548G>A p.K516= | Splice Region (SNP) | VAF 12/46 reads (26%) | catalogued as COSV99173593; called by muse, mutect2
- CCDC60 | c.676C>T p.R226* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | catalogued as rs747656084, COSV100554431; called by muse, mutect2, varscan2
- CCDC88B | c.2076C>A p.D692E | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV100106099; called by muse, mutect2, varscan2
- CCND3 | c.847A>G p.T283A | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV57828739, COSV57829895; called by muse, mutect2, varscan2
- CFAP94 | c.940G>T p.E314* (on ENST00000320267 / NM_001352064.2; = p.E320* on NM_018272.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 125/524 reads (24%) | catalogued as COSV100209264; called by muse, mutect2, varscan2
- COASY | c.856G>A p.V286M | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762699414, COSV99888908; called by muse, mutect2, varscan2
- DCAF8 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV100471005; called by muse, mutect2, varscan2
- DSG1 | c.550G>A p.A184T | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757446872, COSV57138717; called by muse, mutect2, varscan2
- EIF2B4 | c.1304T>A p.L435Q (on ENST00000347454 / NM_001034116.2; = p.L434Q on NM_015636.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100730778; called by muse, mutect2, varscan2
- FBH1 | c.3064G>A p.A1022T (on ENST00000362091 / NM_178150.3; = p.A1073T on NM_032807.4) | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs751196575, COSV62984284; called by muse, varscan2
- FLNC | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100369001; called by muse, mutect2, varscan2
- GCM2 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV101069661; called by muse, mutect2, varscan2
- HMGB2 | c.21C>G p.N7K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99632911; called by muse, mutect2, varscan2
- LRRN3 | c.1021C>A p.L341M | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100074405; called by muse, mutect2, varscan2
- LRRTM4 | c.203T>C p.L68S | Missense Mutation (SNP) | VAF 54/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297766; called by muse, mutect2, varscan2
- MRPL58 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV100042956, COSV100043077; called by muse, mutect2, varscan2
- MS4A8 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); catalogued as COSV55754240; called by muse, mutect2, varscan2
- OR2A5 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 48/190 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV68738612; called by muse, mutect2, varscan2
- OR6C74 | c.702dup p.A235Sfs*36 | Frame Shift Ins (INS) | VAF 32/152 reads (21%) | catalogued as rs1286886511; called by mutect2, varscan2
- PIK3CD | c.595A>G p.S199G | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV100740635; called by muse, mutect2, varscan2
- PKMYT1 | c.116T>A p.F39Y | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99234325; called by muse, mutect2, varscan2
- POLQ | c.5795C>T p.P1932L | Missense Mutation (SNP) | VAF 49/249 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1017580261, COSV99953222; called by muse, mutect2, varscan2
- PPP3R2 | c.426G>T p.K142N | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV100701952; called by muse, mutect2, varscan2
- PRAMEF4 | c.193C>T p.R65C | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.049); catalogued as rs768809656, COSV52438174; called by muse, mutect2, varscan2
- PRRC2B | c.5039G>A p.R1680Q | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.956); catalogued as rs764922838, COSV57644517; called by muse, mutect2, varscan2
- PTX3 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99905061; called by muse, mutect2, varscan2
- SCN3A | c.4700T>G p.V1567G | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as COSV99328997; called by muse, mutect2, varscan2
- SERPINB3 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 47/388 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs111442409, COSV99379727; called by muse, mutect2, varscan2
- SFXN1 | c.277A>G p.M93V | Missense Mutation (SNP) | VAF 43/152 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.377); catalogued as COSV100369460; called by muse, mutect2, varscan2
- SI | c.4042A>G p.T1348A | Missense Mutation (SNP) | VAF 27/147 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.439); catalogued as COSV100017592; called by muse, mutect2, varscan2
- SIN3A | c.430T>G p.Y144D | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100845261, COSV64584271; called by muse, varscan2
- SLC17A4 | c.706G>C p.G236R | Missense Mutation (SNP) | VAF 52/202 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100930705; called by muse, mutect2, varscan2
- THRA | c.748C>T p.L250F | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99225879; called by muse, mutect2, varscan2
- TSKU | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs367560521; called by muse, mutect2, varscan2
- ZBBX | c.1197T>C p.T399= | Splice Region (SNP) | VAF 101/547 reads (18%) | catalogued as COSV100285151; called by muse, mutect2, varscan2
- ZBTB20 | c.1099G>A p.E367K (on ENST00000474710 / NM_001164342.2; = p.E294K on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV61855977; called by muse, mutect2, varscan2
- ZC3H12A | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66103917; called by muse, mutect2, varscan2
- ZNF804B | c.904A>C p.I302L | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV60855536; called by muse, mutect2, varscan2
- ANKRD11 | c.1228dup p.T410Nfs*28 | Frame Shift Ins (INS) | VAF 38/172 reads (22%) | called by mutect2, pindel, varscan2
- BMP3 | c.1073del p.K358Rfs*20 | Frame Shift Del (DEL) | VAF 17/113 reads (15%) | called by mutect2, pindel, varscan2
- SCN1A | c.126dup p.D43Rfs*2 | Frame Shift Ins (INS) | VAF 75/326 reads (23%) | called by mutect2, pindel, varscan2
- APEH | c.1308G>A p.G436= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV99611220; called by muse, mutect2, varscan2
- ASAP3 | c.420A>G p.R140= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV100369793; called by muse, mutect2, varscan2
- COX10 | c.540T>C p.A180= | Silent (SNP) | VAF 41/120 reads (34%) | catalogued as COSV99887264; called by muse, mutect2, varscan2
- CPS1 | c.1539T>C p.A513= | Silent (SNP) | VAF 23/111 reads (21%) | catalogued as COSV99244475; called by muse, mutect2, varscan2
- CYP4F12 | c.675C>A p.I225= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV100216299; called by muse, mutect2, varscan2
- DNAH9 | c.7146C>T p.F2382= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs770011146, COSV52377979; called by muse, mutect2, varscan2
- DSC2 | c.1086A>C p.T362= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as COSV51862974, COSV99199950; called by muse, mutect2, varscan2
- ENPP7 | c.24C>T p.L8= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100093811; called by muse, mutect2, varscan2
- FAT4 | c.6384C>T p.D2128= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as COSV100630665; called by muse, mutect2, varscan2
- GIPC3 | c.372G>A p.L124= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV100461593; called by muse, mutect2, varscan2
- ISYNA1 | c.1161G>A p.P387= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs777014766, COSV54210110; called by muse, mutect2, varscan2
- MAST3 | c.2964C>T p.D988= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as rs369259350; called by muse, mutect2, varscan2
- NSG2 | c.498C>G p.P166= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as COSV100292980; called by muse, mutect2
- RELB | c.627G>A p.R209= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs763597394, COSV99673254; called by muse, mutect2, varscan2
- SLC6A16 | c.942C>T p.L314= | Silent (SNP) | VAF 10/136 reads (7%) | catalogued as COSV100243018; called by muse, mutect2
- SNX21 | c.765C>T p.L255= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV99467934; called by muse, mutect2, varscan2
- UNC13A | c.2760C>T p.S920= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs371816774; called by muse, mutect2, varscan2
- ZIC1 | c.909C>T p.P303= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV99292604; called by muse, mutect2, varscan2
- RICTOR | c.4136+289G>A | Intron (SNP) | VAF 4/16 reads (25%) | catalogued as rs1284479031, COSV99705911; called by muse, mutect2
- SLC38A10 | c.2065+250A>T | Intron (SNP) | VAF 13/75 reads (17%) | catalogued as COSV99918050; called by muse, mutect2, varscan2
